Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6R-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT
Reformatted Report

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

male with recurrent TCC, high grade, at right orifice.

Specimens Submitted:

- 1: SP: Right distal ureter
- 2: SP: Left perivesicle lymph nodes
- 3: SP: Bladder, prostate, seminal vesicles, & perives. l.n.
- 4: SP: Rt. vas deferens
- 5: SP: Lt. vas deferens
- 6: SP: Perirectal tissue
- 7: SP: Lt. pelvic lymph nodes
- 8: SP: Rt. external iliac lymph nodes
- 9: SP: Rt. obturator & hypogastric lymph nodes
- 10: SP: Lt. external iliac lymph nodes
- 11: SP: Hypogastric & presacral lymph nodes
- 12: SP: Lt. obturator & hypogastric lymph nodes
- 13: SP: Distal lt. ureter
- 14: SP: Distal rt. ureter

Pw TSS, prior Tcc was Ta or Tis.

ICD-O-3

Carcinoma, urothelial NOS

8/20/13

Site: Bladder, lateral wall

C67.2

Sp 1/30/14

DIAGNOSIS:

- 1) URETER, RIGHT DISTAL; PARTIAL RESECTION:
- SEGMENT OF URETER WITH SEVERE UROTHELIAL DYSPLASIA ASSOCIATED WITH MARKED INFLAMMATION, BEST SEEN ON THE PERMANENT SECTION.
- NOTE: SEEN IN CONSULTATION WITH
- 2) LYMPH NODE, LEFT PERIVESICLE; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- 3) BLADDER, PROSTATE, SEMINAL VESICLES AND PERIVESICLE LYMPH NODES; CYSTOPROSTATECTOMY:
- UROTHELIAL CARCINOMA, HIGH GRADE. THE PATTERN OF GROWTH IS FLAT. THE TUMOR INVADES INTO THE PERIVESICAL SOFT TISSUES (pT3b). THE TUMOR EXTENDS BEYOND THE BLADDER INTO THE FOLLOWING STRUCTURE(S): URETHRA, PERIURETHRAL GLANDS, PROSTATIC DUCTS WITH MICROSCOPIC INVOLVEMENT OF THE PROSTATIC STROMA, AND SEMINAL VESICLES. VASCULAR INVASION IS PRESENT. PERINEURIAL INVASION IS PRESENT. THE FOLLOWING SURGICAL MARGIN(S) IS (ARE) INVOLVED BY TUMOR: URETHRAL MARGIN. THE NON-NEOPLASTIC MUCOSA SHOWS THE FOLLOWING

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

ABNORMALITY(IES): CHRONIC CYSTITIS WITH EXTENSIVE
DENUDATION. THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED
AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL
NUMBER OF NODES EXAMINED): PERIVESICLE: 0/7. THERE IS ONE
NODULE WITHIN THE PERIVESICLE SOFT TISSUE, WHICH MAY
REPRESENT A COMPLETELY REPLACED LYMPH NODE.

- 4) VAS DEFERENS, RIGHT; VASECTOMY:
- VAS DEFERENS, NEGATIVE FOR TUMOR.
- 5) VAS DEFERENS, LEFT; VASECTOMY:
- VAS DEFERENS, NEGATIVE FOR TUMOR.
- 6) SOFT TISSUE, PERIRECTAL; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.
- 7) "LYMPH NODES", LEFT PELVIC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE. NO LYMPHOID TISSUE PRESENT.
- 8) LYMPH NODES, RIGHT EXTERNAL ILIAC; DISSECTION:
- EIGHT LYMPH NODES, NEGATIVE FOR TUMOR (0/8).
- 9) LYMPH NODES, RIGHT OBTURATOR AND HYPOGASTRIC; DISSECTION:
- SIX LYMPH NODES, NEGATIVE FOR TUMOR (0/6).
- 10) LYMPH NODES, LEFT EXTERNAL ILIAC; DISSECTION:
- FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).
- 11) LYMPH NODES, HYPOGASTRIC AND PRESACRAL; DISSECTION:
- THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).
- 12) LYMPH NODES, LEFT OBTURATOR AND HYPOGASTRIC; DISSECTION:
- SEVEN LYMPH NODES, NEGATIVE FOR TUMOR (0/7).
- 13) URETER, LEFT DISTAL; PARTIAL RESECTION:
- UROTHELIAL MUCOSA WITH CARCINOMA IN SITU.
- 14) URETER, RIGHT DISTAL; PARTIAL RESECTION:
- UROTHELIAL MUCOSA WITH CARCINOMA IN SITU.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE
REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh for frozen section
diagnosis, and is labeled "Right distal ureter". It consists of
a fragment of white-tan tissue surrounded by adipose. The entire
specimen is submitted for frozen section diagnosis.

Summary of sections:

FSC - frozen section control

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

2) The specimen is received fresh for frozen section diagnosis, and is labeled "Left perivesicle lymph nodes". It consists of a tiny piece of rubbery tan tissue measuring 3.0 x 1.2 x 1.0 cm. It is bisected, and half is submitted for frozen section.

Summary of sections:

FSC - frozen section control

U - undesignated remaining unfrozen tissue

3) The specimen is received fresh, labeled "Bladder, Prostate, Seminal Vesicles and Perivesicle Lymph Nodes". It consists of a cystoprostatectomy specimen measuring 14 x 11 x 5 cm and consisting of a urinary bladder, attached segments of bilateral ureters, prostate, seminal vesicles, vasa deferentia and perivesicle adipose tissue. The bladder measures 6 x 5 cm. Attached segment of the right ureter measures 3 cm in length and up to 1 cm in diameter. A segment of left ureter measures 3 cm in length and 0.4 cm in diameter. The right lateral wall of the bladder shows an ulcerated, focally necrotic tumor measuring 3.5 x 2 x 1 cm. The tumor extends to the trigone and to the prostatic urethra. The right ureteral orifice is 0.2 cm from the tumor. It is markedly edematous, congested and the ureter proximal to it is dilated. The tumor has a maximum thickness of 1 cm and appears to extend through the entire wall into the periprostatic fat. The right ureter shows focally hemorrhagic and granular mucosal surface. The left ureteral orifice and the left ureteral mucosa are grossly unremarkable. The remainder of the bladder mucosa is congested and edematous.

The specimen is received fresh and labeled Prostate and Seminal Vesicles. It consists of a radical prostatectomy specimen which includes prostate, seminal vesicles, and portions of right and left vasa deferentia. The specimen weighs 42 gm. The prostate measures 3.6 cm from apex to base, 5.4 cm transversely, and 3.5 cm from anterior to posterior. The right seminal vesicle measures 3.4 x 1.3 x 1.0 cm and the left seminal vesicle measures 2.8 x 1.5 x 1.2 cm. The external surface of the prostate is smooth. The prostate is serially sectioned from apex to base at approximately 3 mm intervals. 100% of the prostate tissue is submitted.

Summary of Sections:

RA - right apical margin

LA - left apical margin

BN - bladder neck margin

RSV - right vas deferens and seminal vesicle

LSV - left vas deferens and seminal vesicle

RP - right prostate (apex to base - A to Z)

LP - left prostate (apex to base - A to Z)

BN - bladder neck

RUM - right ureteral margin

RU - right ureter, granular mucosa

LUM - left ureteral margin

[page 4 of 7]
SURGICAL PATHOLOGY REPORT

RUO - right ureteral orifice
LUO - left ureteral orifice
T - tumor, deepest invasion and deep margin
LW - left bladder wall
AW - anterior bladder wall
PW - posterior wall
D - dome
LN - perivesicle lymph nodes

4) The specimen is received in formalin, labeled "Right Vas Deferens". It consists of a segment of tubular structure measuring 8 cm in length and 0.2 cm in diameter. Representative sections are submitted in one cassette.

Summary of Sections:
U - undesignated

5) The specimen is received in formalin, labeled "Left Vas Deferens". It consists of a segment of tubular structure measuring 2.5 cm in length and 0.2 cm in diameter. Representative sections are submitted in one cassette.

Summary of Sections:
U - undesignated

6) The specimen is received in formalin, labeled "Perirectal Tissue". It consists of one piece of congested fibroadipose tissue measuring 2 x 1 x 0.2 cm. The entire specimen is submitted in one cassette.

Summary of Sections:
U - undesignated

7) The specimen is received in formalin, labeled "Left Pelvic Lymph Nodes". It consists of an irregular portion of congested adipose tissue measuring 4 x 4 x 0.6 cm. Possible lymph nodes are submitted in one cassette.

Summary of Sections:
U - undesignated

8) The specimen is received in formalin, labeled "Right External Iliac Lymph Nodes". It consists of soft pink-tan lymph nodes ranging in size from 0.3 x 0.3 cm to 2 x 0.7 x 0.6 cm. The nodes are submitted entirely in two cassettes.

Summary of Sections:
U - undesignated

[page 5 of 7]
SURGICAL PATHOLOGY REPORT

9) The specimen is received in formalin, labeled "Right Obturator and Hypogastric Lymph Nodes". It consists of soft pink-tan lymph nodes ranging in size from 1.3 x 0.6 x 0.4 cm to 2 x 1 x 0.5 cm. The nodes are submitted entirely.

Summary of Sections:

U - undesignated

10) The specimen is received in formalin, labeled "Left External Iliac Lymph Nodes". It consists of a portion of adipose tissue measuring 3 x 1 x 1 cm, containing soft pink-tan lymph nodes measuring up to 0.7 cm. The nodes are submitted entirely in one cassette.

Summary of Sections:

U - undesignated

11) The specimen is received in formalin, labeled "Hypogastric and Presacral Lymph Nodes". It consists of multiple fragments of adipose tissue aggregating to 4 x 4 x 1 cm and containing soft pink-tan lymph nodes. The nodes are submitted entirely in two cassettes.

Summary of Sections:

U - undesignated

12) The specimen is received in formalin, labeled "Left Obturator and Hypogastric Lymph Nodes". It consists of a portion of adipose tissue measuring 5.5 x 3.5 x 1 cm, containing soft pink-tan lymph nodes. The nodes are submitted entirely in two cassettes.

Summary of Sections:

U - undesignated

13) The specimen is received in formalin, labeled "Distal Left Ureter (stitch marks distal margin)". It consists of a segment of tubular structure measuring 5 cm in length and up to 1 cm in diameter. The wall appears edematous. The distal margin, marked with a suture, is submitted in one cassette.

Summary of Sections:

DM - distal margin

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

14) The specimen is received in formalin, labeled "Distal Right Ureter (stitch marks most distal margin)". It consists of a segment of tubular structure measuring 4 cm in length and up to 1 cm in diameter. The distal margin, marked with a suture, is submitted in one cassette.

Summary of Sections:

DM - distal margin

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	1	Y
2	FSC		1	1	Y
	U		1	1	
3	A		1	1	N
	AW		1	1	
	B		1	1	
	BN		2	M	
	C		1	1	
	D		2	2	
	E		1	1	
	F		1	1	
	LN		2	M	
	LUM		1	1	
	LUO		1	1	
	LW		1	1	
	PW		1	1	
	RU		1	1	
	RUM		1	1	
	RUO		1	1	
	T		4	M	
	la		1	M	
	lsv		1	M	
	ra		1	M	
	rsv		1	M	
4	U		1	M	N
5	U		1	M	N
6	U		1	1	Y
7	U		1	M	N
8	U		2	M	
9	U		2	M	Y
10	U		1	M	N
11	U		2	M	N
12	U		2	M	N
13	DM		1	1	N
14	DM		1	1	N

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN INFLAMMATORY ATYPIA SEEN
IN CONSULTATION WITH
PERMANENT DIAGNOSIS: SEE FINAL DIAGNOSIS.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

[page 7 of 7]
SURGICAL PATHOLOGY REPORT

Pw TSS, BCG for initial
Ta/Tis end $\leq$

Source: NCI Genomic Data Commons file 569512c1-f1c6-4081-bba8-cd22bed527e1 (TCGA-DK-AA6R.4A588484-5C6C-4ACF-8AA6-8BE9F1AE804C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).